Somatic mutation profile of tumor specimen TCGA-SP-A6QD-01A (aliquot TCGA-SP-A6QD-01A-12D-A35I-08) from TCGA case TCGA-SP-A6QD, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 26.9 years (9,829 days).
Specimen TCGA-SP-A6QD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a0d1bb7-c10a-4e7d-bd89-b77df226c2fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SP-A6QD-10A (Blood Derived Normal), aliquot TCGA-SP-A6QD-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1da98f7-8280-45e6-9ec6-7a8607511e59

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 2, Missense Mutation 2, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH1 | c.6829C>T p.R2277W | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs749114791, COSV70228285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR8H3 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57908144, COSV57908895; called by muse, mutect2, varscan2
- CAMK2N1 | c.96del p.N33Tfs*35 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | called by mutect2, pindel, varscan2
- TPBG | c.426del p.S143Afs*36 | Frame Shift Del (DEL) | VAF 28/69 reads (41%) | called by mutect2, pindel, varscan2
- FIG4 | c.105A>G p.K35= | Silent (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- PDPN | c.-80G>C | 5'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
